FM case AD6854 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/c98c0114-75d7-457f-ba3b-b6b62b5a9231

Female, 35.7 years: Carcinoma, NOS (ICD-O-3 8010/3) of the thyroid gland; metastasis biopsied or resected from the bone. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
